FM case AD17662 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Complex Epithelial Neoplasms; Primary site: Breast.
https://portal.gdc.cancer.gov/cases/8e2f31df-ba90-4b8d-8c37-5140bc957524

Female, 70.5 years: Metaplastic carcinoma, NOS (ICD-O-3 8575/3) of the breast; primary biopsied or resected from the breast. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
